Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BN, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BN-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with large deep soft tissue mass medial thigh, needle biopsy consistent with sarcoma.

Specimens Submitted:

- 1: Proximal margin left thigh (fs)
- 2: Proximal margin # 2 left thigh (fs)
- 3: Left thigh mass

DIAGNOSIS:

1. Soft tissue, proximal margin left thigh; excision:
- Skeletal muscle with atrophy and chronic inflammation.
- No tumor seen.
2. Soft tissue, proximal margin # 2 left thigh; excision:
- Skeletal muscle with atrophy and chronic inflammation.
- No tumor seen.
3. Soft tissue, left thigh; resection:
- High grade Pleomorphic sarcoma (MFH), involving skeletal muscle.
- The tumor measures 10.9 cm in greatest dimension.
- Resection margins are free of tumor.
- Closest margin is the medial margin with a clearance of < 1 mm.

Note: Immunohistochemical stains show that the tumor cells are positive for vimentin and CD34, while negative for AE1:AE3, SMA, desmin, CD117, CDK4, MDM2, and S100. There is patchy positivity for BCL2. Based on the morphology and the immunoprofile, the findings are consistent with a high grade pleomorphic sarcoma.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the [REDACTED]. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

** Continued on next page **

CSCF ICD-O-3
Sarcoma, pleomorphic, undifferentiated
8802/3 8805/3
Code to highest 8805/3
path Histocytoma fibrous malignant 8836/3
Site @ Thigh NOS C49.2

QW 11/22/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

--- Report Electronically Signed Out ---

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled,
"Proximal margin left thigh (fs)" and consists of a fragment of soft pink-
tan tissue (0.5x 0.3x 0.2 cm). The specimen is entirely frozen and submitted
in one cassette.

Summary of sections:

FSC- frozen section control

2. The specimen is received fresh for frozen section consultation, labeled,
"Proximal margin # 2 left thigh (fs)" and consists of a fragment of soft
white-pink tissue (0.7x 0.3x 0.2 cm). The specimen is entirely frozen and
submitted in one cassette.

Summary of sections:

FSC- frozen section control

3. The specimen is received fresh, labeled "left thigh mass, black
stitch-proximal, white stitch-deep right periosteum, green stitch-medial".
It consists of a soft tissue mass measuring 11.5 x 6 x 5 cm. There is
attached skeletal muscle along the deep aspect measuring 9 x 5 cm. The
margins are inked as follows: - proximal green, distal yellow, deep blue,
medial black, lateral orange/black. The specimen is serially sectioned
revealing a round, well circumscribed, white fleshy mass measuring 10.9 x
6.1 x 4.0 cm. There is approximately 10% necrosis. The tumor is 0.5 cm from
the proximal margin, 2.9 cm from the distal margin, 0.1 from the medial
margin, and 0.7 cm from the deep margin. TPS is submitted. Photographs are
taken. Representative sections are submitted.

Summary of sections:

PM proximal margin

DM distal margin

MM medial margin

LM lateral margin

D deep margin

AM anterior margin

T tumor

T9-additional tumor to lateral margin

T10-additional tumor to medial margin

T11-additional tumor to lateral margin

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: Proximal margin left thigh

Block	Sect.	Site	PCs
1	FSC		1

Part 2: Proximal margin # 2 left thigh

Block	Sect.	Site	PCs
1	FSC		1

Part 3: Left thigh mass

Block	Sect.	Site	PCs
1	AM		1
1	D		1
1	DM		1
1	LM		1
1	MM		1
1	PM		1
5	T		5

Intraoperative Consultation:

1. Proximal margin left thigh (fs): Skeletal muscle with inflammation, no definite tumor
Permanent diagnosis: Same.

2. Proximal margin # 2 left thigh (fs): No definite tumor
Permanent diagnosis: Same.

1. Proximal margin left thigh (fs): Skeletal muscle with inflammation, no definite tumor)
Permanent diagnosis: Same.

2. Proximal margin # 2 left thigh (fs): No definite tumor
Permanent diagnosis: Same.

** End of Report **

10/29/13

HIFAA Discrepancy		✓

Source: NCI Genomic Data Commons file 9ca12e15-0cbe-4faa-bfed-31b4f227cace (TCGA-DX-A8BN.1200C86F-1749-4487-B4A3-D2F3C53DDA72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).